Somatic mutation profile of tumor specimen MP2PRT-PASCJM-TMP1-A (aliquot MP2PRT-PASCJM-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASCJM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.1 years (7,712 days).
Specimen MP2PRT-PASCJM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0523f989-f6dd-49cb-a0c9-f2dcfc3aeb3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASCJM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASCJM-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5599299d-ddca-424e-9eba-677a16956976

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 200/338 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606920, CM100127, COSV54736394, COSV54741067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.379T>C p.S127P | Missense Mutation (SNP) | VAF 106/135 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- CCNE2 | c.912dup p.T305Yfs*4 | Frame Shift Ins (INS) | VAF 82/352 reads (23%) | catalogued as rs1563679021; called by mutect2, pindel, varscan2
- CHL1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs150837773; called by muse, mutect2, varscan2
- DCSTAMP | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 75/745 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs566008351, COSV52576605; called by muse, mutect2
- DPH1 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 120/159 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV53983930; called by muse, mutect2, varscan2
- HDAC2 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.98); catalogued as COSV64037561; called by muse, mutect2
- IGLV3-22 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs530284832; called by muse, mutect2, varscan2
- KMT2D | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 241/332 reads (73%) | catalogued as CM105487, COSV56420226; called by muse, mutect2, varscan2
- KRT36 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs201247809, COSV60202450; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.147C>G p.D49E | Missense Mutation (SNP) | VAF 175/538 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV53276412; called by muse, mutect2, varscan2
- NCALD | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 103/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777310976, COSV55271463; called by muse, mutect2, varscan2
- NNMT | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs1167168437, COSV55473175; called by muse, mutect2, varscan2
- NPTN | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1205697454, COSV54737061; called by muse, mutect2, varscan2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by muse, mutect2
- PLPPR4 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs748074486, COSV64564294; called by muse, mutect2, varscan2
- PPP1R9A | c.2359G>T p.A787S | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV56884932; called by muse, varscan2
- RBM5 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61736835; called by muse, mutect2, varscan2
- SHANK2 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 418/681 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as rs562398920, COSV53589656; called by muse, mutect2, varscan2
- ZMYND12 | c.773C>A p.A258D | Missense Mutation (SNP) | VAF 129/221 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV65341746; called by muse, mutect2, varscan2
- DNAH14 | c.5290A>C p.I1764L (on ENST00000445597; = p.I2169L on NM_001367479.1) | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.106); called by muse, mutect2
- USF3 | c.5711_5713del p.G1904del | In Frame Del (DEL) | VAF 30/277 reads (11%) | called by mutect2, pindel, varscan2
- ZNF805 | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DISP3 | c.1077G>A p.Q359= | Silent (SNP) | VAF 19/370 reads (5%) | called by muse, mutect2
- HPS1 | c.81G>A p.R27= | Silent (SNP) | VAF 78/287 reads (27%) | catalogued as COSV57266871; called by muse, mutect2, varscan2
- LRP2 | c.9366C>T p.C3122= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as rs772986118, COSV55545035; called by muse, mutect2
- P3H2 | c.1575G>A p.L525= | Silent (SNP) | VAF 78/200 reads (39%) | catalogued as COSV60019361; called by muse, mutect2, varscan2
- SEMA3C | c.675T>C p.D225= | Silent (SNP) | VAF 15/215 reads (7%) | called by muse, mutect2
- SLC25A47 | c.876C>G p.V292= | Silent (SNP) | VAF 58/290 reads (20%) | catalogued as rs1396893861, COSV59924742; called by muse, mutect2, varscan2
- TMEM108 | c.765G>A p.A255= | Silent (SNP) | VAF 42/352 reads (12%) | catalogued as rs751525194, COSV58865347; called by muse, mutect2, varscan2
- TRPM6 | c.3342C>T p.L1114= | Silent (SNP) | VAF 177/277 reads (64%) | catalogued as COSV62504882; called by muse, mutect2, varscan2
